Somatic mutation profile of tumor specimen TCGA-3E-AAAY-01A (aliquot TCGA-3E-AAAY-01A-11D-A38G-08) from TCGA case TCGA-3E-AAAY, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 67.8 years (24,760 days).
Specimen TCGA-3E-AAAY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c278c20f-d11f-4b66-bd27-86f39bfe7674.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3E-AAAY-10A (Blood Derived Normal), aliquot TCGA-3E-AAAY-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d516940e-0c66-43cb-9033-6c2635c0c8e5

The open-access MAF lists 27 somatic variants for this specimen: 16 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 10, Nonsense Mutation 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A1 | c.977G>A p.G326D | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72645356, CM070721; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 18/178 reads (10%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by mutect2, varscan2
- ABTB2 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 12/272 reads (4%) | catalogued as rs1362247982, COSV100130597; called by muse, mutect2
- BAZ1B | c.1766A>C p.N589T | Missense Mutation (SNP) | VAF 78/1173 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100289553; called by muse, mutect2
- FBXL5 | c.1277T>C p.I426T | Missense Mutation (SNP) | VAF 36/396 reads (9%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV100377635; called by muse, mutect2
- IPO5 | c.2974G>T p.V992F | Missense Mutation (SNP) | VAF 33/532 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.318); catalogued as COSV55152018; called by muse, mutect2
- KCNH3 | c.2515T>C p.F839L | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV99234670; called by muse, mutect2
- MAZ | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV99360811, COSV99361351; called by muse, mutect2
- PCDHB3 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV50600078; called by muse, mutect2
- RASGEF1C | c.764T>G p.F255C | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100745511; called by muse, mutect2
- RTKN2 | c.277A>G p.K93E | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100859708; called by muse, mutect2
- SRPX2 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757158053, COSV99342616; called by muse, mutect2, varscan2
- TGFBR1 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 46/568 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV66626042, COSV66627342; called by muse, mutect2
- TRAPPC10 | c.679-1G>A p.X227_splice | Splice Site (SNP) | VAF 16/324 reads (5%) | catalogued as COSV99378137; called by muse, mutect2
- ZNF613 | c.1313G>A p.S438N (on ENST00000293471 / NM_001031721.4; = p.S402N on NM_024840.4) | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV99522825; called by muse, mutect2
- ZPLD1 | c.1117G>A p.A373T (on ENST00000466937 / NM_001329788.1; = p.A389T on NM_175056.2) | Missense Mutation (SNP) | VAF 48/1114 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs79539385, COSV60351917; called by muse, mutect2
- ABHD8 | c.57C>T p.N19= | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as rs546146109, COSV53113024; called by muse, mutect2, varscan2
- C9orf24 | c.444T>A p.P148= | Silent (SNP) | VAF 32/430 reads (7%) | catalogued as COSV99897679; called by muse, mutect2
- IGF2 | c.438C>T p.S146= (on ENST00000434045 / NM_001127598.3; = p.S90= on NM_000612.6) | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as rs373036890; called by muse, mutect2
- METTL21C | c.267G>A p.A89= | Silent (SNP) | VAF 24/216 reads (11%) | catalogued as rs781756632, COSV57432872, COSV99940133; called by muse, mutect2
- NLRP2 | c.2382C>T p.S794= | Silent (SNP) | VAF 26/344 reads (8%) | catalogued as rs148932752; called by muse, mutect2
- POM121C | c.1905G>T p.P635= (on ENST00000607367; = p.P393= on NM_001099415.3) | Silent (SNP) | VAF 7/136 reads (5%) | called by muse, mutect2
- RETN | c.303G>A p.A101= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99679342; called by muse, mutect2
- SAG | c.237C>T p.I79= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs762679217, COSV101300636, COSV101300693; called by muse, mutect2
- SIGLEC7 | c.570C>G p.S190= | Silent (SNP) | VAF 22/452 reads (5%) | catalogued as COSV99978414; called by muse, mutect2
- TAL1 | c.657G>A p.P219= | Silent (SNP) | VAF 28/418 reads (7%) | catalogued as rs1424449717, COSV53747833; called by muse, mutect2
- GRM7 | c.2698+6126A>C | Intron (SNP) | VAF 47/814 reads (6%) | catalogued as rs754728660, COSV100735519; called by muse, mutect2
